CGCI case BLGSP-71-27-00424 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/255d3ca7-aaaa-4cef-9be1-8794d9d55312

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 45.3 years (16,555 days); Year of diagnosis: 2010; Method of diagnosis: Core Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,535 days (6.9 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Cervical lymph nodes; Sites of involvement: Soft tissue / Colon, NOS / Pericardium / Peritoneum, NOS / Omentum.
   Pathology details: Lymph node involved site: Retroperitoneal.
   Pathology details: Lymph node involved site: Iliac-external.
   Pathology details: Lymph node involved site: Mesenteric.
   Pathology details: Lymph node involved site: Mediastinal.
   Pathology details: Lymph node involved site: Supraclavicular.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Iliac, NOS; Tumor largest dimension diameter: 2.3 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHOP-21; Days to treatment start: 1 day; Days to treatment end: 5 days; Number of cycles: 1.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Methotrexate + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 1 day; Days to treatment end: 5 days; Number of cycles: 1.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Days to treatment start: 20 days; Days to treatment end: 124 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 0.
- Days to follow up: 2,535 days (6.9 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day -442.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD23 (IHC): Negative.
- CD3 (IHC): Negative.
- CD5 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Test (IHC): Negative; Specialized molecular test: CD21.
- Test (IHC): Negative; Specialized molecular test: TdT.
- Lactate Dehydrogenase 2925 [Blood test normal range upper: 250].

Other clinical attributes
- Day -442: Comorbidities: HIV/AIDS.
- Day -442: Risk factors: HIV/AIDS.
- Day 0: Weight: 95.1 kg; Height: 185 cm; BMI: 27.8; CD4 count: 0; Haart treatment indicator: Yes; HIV viral load: 709.
- Day 0: Risk factors: Syphilis.
- Day 0: Comorbidities: Syphilis.
- Day 0: Cdc hiv risk factors: Intravenous Drug User.
- Day 2,535: Nadir CD4 count: 76.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-27-00424-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-27-00424-01A-01-S1-HE: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 10; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-27-00424-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Cd4 counts at diagnosis: 0; Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes; Cdc HIV risk group: IV drug user; History immunosuppresive diagnosis other: syphillis.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 5; Extranodal involvment other: peritoneum, omentum; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: Iliac.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 2925; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD5.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD21.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: CD23.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: TdT.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CHOP-21 + rituximab + intrathecal methotrexate; Pharma adjuvant cycles count: 1.
- Treatments, Treatment 2: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharma adjuvant cycles count: 6.
